Somatic mutation profile of tumor specimen MP2PRT-PAUKLH-TMP1-A (aliquot MP2PRT-PAUKLH-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUKLH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,742 days).
Specimen MP2PRT-PAUKLH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c2ef0f8-e68a-43b7-9004-6c0df856d383.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKLH-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKLH-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be8e7157-caff-4085-9315-3a6b741da936

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 1, Silent 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 116/318 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- HLA-E | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 134/405 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV64927906; called by muse, mutect2, varscan2
- KDM6A | c.3337_3338insGT p.V1113Gfs*8 | Frame Shift Ins (INS) | VAF 176/540 reads (33%) | catalogued as COSV100938063, COSV65036957, COSV65039213, COSV65040599, COSV65042718, COSV65043394, COSV99060695; called by mutect2, pindel, varscan2
- SLC5A5 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 121/433 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs921276817, COSV55833548; called by muse, mutect2, varscan2
- TP53 | c.847_848insAGG p.R283delinsQG | In Frame Ins (INS) | VAF 117/458 reads (26%) | catalogued as COSV53297573, COSV99037230; called by mutect2, pindel*, varscan2
- ULK4 | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 11/251 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.389); catalogued as rs1043123386; called by muse, mutect2
- ZC3H11B | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 190/448 reads (42%) | catalogued as rs1321827959; called by muse, mutect2, varscan2
- ARSJ | c.1212G>T p.W404C | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC25A28 | c.702G>A p.M234I | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- DTX1 | c.1317C>G p.G439= | Silent (SNP) | VAF 195/617 reads (32%) | called by muse, mutect2, varscan2
